Gene-level copy-number profile of tumor specimen TCGA-FD-A6TB-01A from TCGA case TCGA-FD-A6TB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.6 years (30,185 days).
Specimen TCGA-FD-A6TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c36f1739-5f07-4662-bdc2-8834233e531a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3286078e-b041-4ac9-9db9-aa4a8b12c2a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 11,831; copy number 2: 44,236; copy number 3: 3,264; copy number 4: 26; copy number 5: 281; copy number 10: 29; copy number 11: 78; copy number 12: 10; copy number 13: 35; copy number 14: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TB-01A-12D-A338-01): tumor purity 0.28, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 450 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,686,951–69,959,097, 34 genes, copy number 13 (within-gene range 2–13): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 13: AC078922.1.
- chr12:100,573,683–101,386,618, 10 genes, copy number 12 (within-gene range 2–12): GAS2L3, PIGAP1, ANO4, AC138360.1, AC063947.1, SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20.
- chr12:102,063,355–103,179,247, 17 genes, copy number 14 (within-gene range 2–14): AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1, LINC00485, PAH, AC026108.1, ASCL1, AC026108.2, AC068643.1, AC068643.2.
- chr12:111,034,165–115,886,137, 106 genes, copy number 10–11 (broad region; genes not listed).
- chr12:115,961,187–115,962,733, 1 gene, copy number 10: AC012157.2.
- chr20:30,278,906–38,651,035, 281 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
